Somatic mutation profile of tumor specimen MMRF_2373_2_BM_CD138pos (aliquot MMRF_2373_2_BM_CD138pos_T1_KHS5U_L14857) from MMRF case MMRF_2373, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.1 years (24,525 days).
Specimen MMRF_2373_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df8cfcde-8b3b-4f02-818e-0b1f4d2f46d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2373_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2373_1_PB_CD3pos_C1_KHS5U_K14033; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34961e30-8ee0-4da2-bf26-04db00790865

The open-access MAF lists 285 somatic variants for this specimen: 103 protein-altering or splice-affecting, 29 silent, 153 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, 3'UTR 82, Intron 48, Silent 29, 3'Flank 9, Nonsense Mutation 7, 5'Flank 6, RNA 4, 5'UTR 4, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 86/86 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACKR1 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs746013760; called by muse, mutect2, varscan2
- ADAMTS10 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV54354947; called by muse, mutect2, varscan2
- AFAP1L1 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368271604; called by muse, mutect2, varscan2
- ARNT2 | c.1735C>G p.P579A | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV57581175, COSV57582923; called by muse, mutect2, varscan2
- ARSB | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1339096448, CM1312580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRINP3 | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as rs1281342247; called by muse, mutect2
- C2CD3 | c.3871G>T p.E1291* | Nonsense Mutation (SNP) | VAF 28/306 reads (9%) | catalogued as COSV58099084; called by muse, mutect2
- CACNA1E | c.5881C>T p.Q1961* | Nonsense Mutation (SNP) | VAF 39/196 reads (20%) | catalogued as COSV62381081; called by muse, mutect2, varscan2
- CAMSAP1 | c.2219C>T p.S740L | Missense Mutation (SNP) | VAF 215/449 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.582); catalogued as rs769853731; called by muse, mutect2, varscan2
- CASP8AP2 | c.5021C>T p.S1674F | Missense Mutation (SNP) | VAF 9/270 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV99387120; called by muse, mutect2
- CNTLN | c.3652G>A p.E1218K | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as rs1173032868; called by muse, mutect2, varscan2
- COL6A1 | c.1075G>A p.G359S | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1223868298; called by muse, mutect2
- CWC27 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.941); catalogued as rs914036534; called by muse, mutect2, varscan2
- DOP1A | c.3373G>C p.E1125Q | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.308); catalogued as COSV99381938; called by muse, mutect2, varscan2
- DUSP19 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61193526; called by muse, mutect2, varscan2
- IL1R1 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 72/543 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV52105249; called by muse, mutect2, varscan2
- KCNMA1 | c.1559G>C p.R520T | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54240311; called by muse, mutect2, varscan2
- KCNS1 | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 91/91 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262560671, COSV100066944; called by muse, mutect2, varscan2
- KLRC4 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 60/284 reads (21%) | catalogued as rs903097406; called by muse, mutect2, varscan2
- LRRC52 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs769884053, COSV54233994; called by muse, mutect2, varscan2
- METTL26 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 43/159 reads (27%) | catalogued as rs755916265; called by muse, mutect2, varscan2
- NKX2-2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.173); catalogued as COSV101010631; called by muse, mutect2
- OLFML2B | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as rs1384537560; called by muse, mutect2, varscan2
- OR4A47 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 83/143 reads (58%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as rs1468528217; called by muse, mutect2, varscan2
- PLEKHG1 | c.3986C>T p.T1329I | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1191783858; called by muse, mutect2
- PODXL | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.005); catalogued as rs377478180; called by muse, mutect2, varscan2
- PTBP1 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs745923877; called by muse, mutect2, varscan2
- SHOC1 | c.2317C>T p.H773Y | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59499101; called by muse, mutect2, varscan2
- SLC1A7 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT tolerated (0.76); PolyPhen benign (0.041); catalogued as rs149217403, COSV65194231; called by muse, mutect2, varscan2
- SPTBN4 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs775127507, COSV100151792; called by muse, mutect2, varscan2
- TMPRSS4 | c.1289A>G p.Y430C | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs762712812; called by muse, mutect2
- TMSB4X | c.-17+1G>A | Splice Site (SNP) | VAF 124/124 reads (100%) | catalogued as COSV66081196, COSV66081636; called by muse, varscan2
- TNK2 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 97/183 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as rs1202675063; called by muse, mutect2, varscan2
- TP53BP2 | c.2329C>A p.P777T (on ENST00000343537 / NM_001031685.3; = p.P648T on NM_005426.2) | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59074076; called by muse, mutect2, varscan2
- WDFY4 | c.9056G>T p.R3019L | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs969942181; called by muse, mutect2
- WDR70 | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 97/381 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs761947995, COSV54273336; called by muse, mutect2, varscan2
- ZNF878 | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV72155966; called by muse, mutect2
- ZZEF1 | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 190/357 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67556889; called by muse, mutect2, varscan2
- ADGRL1 | c.3947G>A p.G1316D (on ENST00000340736 / NM_001008701.3; = p.G1311D on NM_014921.5) | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- AGRN | c.3824C>T p.T1275I | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); called by muse, mutect2
- ARFGEF2 | c.2702T>A p.L901Q | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- C20orf144 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C9orf131 | c.1085T>G p.L362R | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.059); called by muse, mutect2
- CD19 | c.1210G>C p.E404Q | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- CEP78 | c.602A>T p.K201M | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CFH | c.945A>G p.I315M | Missense Mutation (SNP) | VAF 65/468 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CFH | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 67/462 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- CYP26B1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 99/384 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DACH1 | c.1731G>T p.E577D (on ENST00000619232 / NM_001366712.1; = p.E323D on NM_004392.6) | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.013); called by muse, mutect2
- DNAH3 | c.818A>G p.E273G | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DPEP3 | c.854C>G p.P285R | Missense Mutation (SNP) | VAF 65/96 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EFCAB8 | c.1679A>T p.E560V | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- FAR2 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FREM3 | c.5305C>A p.H1769N | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- FRMPD4 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP2 | c.3357G>T p.K1119N | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2
- HEPHL1 | c.1905A>T p.L635F | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IQCA1 | c.452A>T p.D151V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IRX1 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- IZUMO3 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.09); called by muse, mutect2
- KDM3A | c.1967A>T p.K656I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2
- KIAA0586 | c.2653A>G p.K885E (on ENST00000619416 / NM_001244190.2; = p.K824E on NM_014749.5) | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.248); called by muse, mutect2
- KIF5C | c.2726G>C p.R909P | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KLHL7 | c.1446G>C p.K482N (on ENST00000339077 / NM_001031710.3; = p.K434N on NM_018846.5) | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.145); called by muse, mutect2
- LAG3 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.863); called by muse, mutect2
- LIFR | c.2516C>T p.A839V | Missense Mutation (SNP) | VAF 55/393 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LOXHD1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRC53 | c.2122dup p.L708Pfs*6 | Frame Shift Ins (INS) | VAF 96/216 reads (44%) | called by mutect2, pindel, varscan2
- MFHAS1 | c.1199C>A p.A400D | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- MUC16 | c.2655G>T p.R885S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); called by muse, mutect2
- NASP | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NHSL2 | c.112G>T p.A38S (on ENST00000510661; = p.A404S on NM_001013627.2) | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NKX2-1 | c.739C>A p.Q247K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.857); called by muse, mutect2
- NRAP | c.4169C>A p.A1390E (on ENST00000359988 / NM_001322945.2; = p.A1355E on NM_006175.4) | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- OR52I2 | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 83/580 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PDXP | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PIM3 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- PLAA | c.2124C>G p.N708K | Missense Mutation (SNP) | VAF 113/236 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PM20D2 | c.747G>A p.W249* | Nonsense Mutation (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- PPP1R1A | c.470C>G p.S157* | Nonsense Mutation (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2, varscan2
- PWWP2A | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- RBAK | c.2036A>G p.Y679C | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RBM26 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- RETREG3 | c.246dup p.A83Cfs*22 | Frame Shift Ins (INS) | VAF 36/167 reads (22%) | called by mutect2, pindel, varscan2
- RETSAT | c.768G>C p.Q256H | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2
- SEMA6A | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- SIGLEC9 | c.788C>A p.P263Q | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC17A5 | c.1096A>G p.I366V | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC25A47 | c.740C>A p.A247E | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- SPEG | c.7219C>T p.R2407C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPOP | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SV2A | c.1045G>T p.G349W | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SYNE1 | c.10000G>C p.E3334Q (on ENST00000367255 / NM_182961.4; = p.E3341Q on NM_033071.3) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TARBP1 | c.3137C>G p.S1046C | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TRAF7 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- UBE2G1 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- URB1 | c.4921T>G p.C1641G | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- VASH1 | c.728T>C p.F243S | Missense Mutation (SNP) | VAF 58/58 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, varscan2
- ZFP69 | c.112A>G p.M38V | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- ZFR | c.2668C>G p.P890A | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF679 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 128/413 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ZRANB1 | c.2090C>T p.S697F | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADCY9 | c.1740C>G p.R580= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as rs753494465; called by muse, mutect2, varscan2
- AKT3 | c.633G>A p.L211= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as rs550697644, COSV55627115; called by muse, mutect2, varscan2
- ARHGAP44 | c.687C>T p.S229= | Silent (SNP) | VAF 49/87 reads (56%) | called by muse, mutect2, varscan2
- CELSR3 | c.2805C>T p.D935= | Silent (SNP) | VAF 35/168 reads (21%) | catalogued as rs1559482000; called by muse, mutect2, varscan2
- CHRND | c.993C>A p.L331= | Silent (SNP) | VAF 30/292 reads (10%) | called by muse, mutect2
- DPP9 | c.1992C>G p.L664= (on ENST00000598800; = p.L693= on NM_139159.5) | Silent (SNP) | VAF 29/264 reads (11%) | called by muse, mutect2, varscan2
- EEF2 | c.1749C>T p.V583= | Silent (SNP) | VAF 50/360 reads (14%) | called by muse, varscan2
- ELMO2 | c.958A>C p.R320= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- GRIFIN | c.372C>T p.D124= | Silent (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- GTF2IRD1 | c.2718G>A p.S906= (on ENST00000265755 / NM_016328.3; = p.S891= on NM_005685.4) | Silent (SNP) | VAF 33/355 reads (9%) | catalogued as rs782163918; called by muse, mutect2
- IGHV2-70 | c.282C>G p.T94= | Silent (SNP) | VAF 53/55 reads (96%) | catalogued as rs368464634; called by muse, mutect2, varscan2
- IGLL5 | c.115C>T p.L39= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs763474712, COSV73248991, COSV73251236, COSV73251304; called by muse, mutect2, varscan2
- LAMA5 | c.8430G>T p.L2810= | Silent (SNP) | VAF 124/282 reads (44%) | catalogued as rs1175850144; called by muse, mutect2, varscan2
- LILRA2 | c.180A>G p.L60= | Silent (SNP) | VAF 9/272 reads (3%) | catalogued as rs1396652912; called by muse, mutect2
- MAPK10 | c.1068C>T p.I356= (on ENST00000359221 / NM_001351625.2; = p.I394= on NM_002753.5) | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV60378288; called by muse, mutect2
- MYH3 | c.1602C>T p.I534= | Silent (SNP) | VAF 55/200 reads (28%) | called by muse, mutect2, varscan2
- OR4C6 | c.861G>A p.L287= | Silent (SNP) | VAF 69/313 reads (22%) | catalogued as COSV58605815; called by muse, mutect2, varscan2
- OR51S1 | c.816G>A p.E272= | Silent (SNP) | VAF 68/291 reads (23%) | called by muse, mutect2, varscan2
- PLPBP | c.333C>T p.L111= | Silent (SNP) | VAF 15/369 reads (4%) | called by muse, mutect2
- PNPLA6 | c.4127G>A p.*1376= (on ENST00000414982 / NM_001166111.2; = p.*1328= on NM_006702.5) | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as rs1367193489; called by muse, mutect2, varscan2
- PRKDC | c.11055C>T p.P3685= | Silent (SNP) | VAF 12/264 reads (5%) | catalogued as COSV58065376; called by muse, mutect2
- PRRG2 | c.51C>T p.C17= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs748810858; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3573C>T p.F1191= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV62785809; called by muse, mutect2, varscan2
- RP1L1 | c.1974A>G p.R658= | Silent (SNP) | VAF 44/101 reads (44%) | called by muse, mutect2, varscan2
- RPS5 | c.573G>A p.K191= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as rs3193532; called by muse, mutect2
- S1PR2 | c.73C>T p.L25= | Silent (SNP) | VAF 46/332 reads (14%) | catalogued as COSV100495371; called by muse, mutect2, varscan2
- SLCO5A1 | c.2311A>C p.R771= | Silent (SNP) | VAF 105/439 reads (24%) | called by muse, mutect2, varscan2
- UMODL1 | c.2209C>T p.L737= (on ENST00000408910 / NM_001004416.2; = p.L865= on NM_173568.3) | Silent (SNP) | VAF 43/203 reads (21%) | called by muse, mutect2, varscan2
- ZNF347 | c.2160C>T p.V720= | Silent (SNP) | VAF 64/463 reads (14%) | catalogued as COSV61970808; called by muse, mutect2, varscan2
- AC022415.2 | c.*1276G>T | 3'UTR (SNP) | VAF 39/377 reads (10%) | called by muse, mutect2, varscan2
- AC105001.2 | c.-19G>A | 5'UTR (SNP) | VAF 146/302 reads (48%) | catalogued as rs761666883; called by muse, mutect2
- ACAT2 | chr6:159761661 ins C | 5'Flank (INS) | VAF 32/334 reads (10%) | catalogued as rs776404057; called by mutect2, pindel
- ADAM17 | c.*792A>C | 3'UTR (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.1944A>T | RNA (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- ADAP2 | c.*403C>G | 3'UTR (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- AHRR | c.*356A>G | 3'UTR (SNP) | VAF 16/76 reads (21%) | catalogued as rs567450092; called by muse, varscan2
- ANKMY1 | c.1565+737C>A | Intron (SNP) | VAF 96/235 reads (41%) | called by muse, mutect2, varscan2
- ANKRD53 | c.783-69C>T | Intron (SNP) | VAF 18/60 reads (30%) | called by muse, varscan2
- AP000769.5 | chr11:65500297 C>T | 5'Flank (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- AP001993.1 | chr11:127101163 G>C | 3'Flank (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.*601C>T | 3'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- ARID4A | c.*565G>A | 3'UTR (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100794640; called by muse, mutect2, varscan2
- ATF6 | c.*2814G>T | 3'UTR (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- BCL2 | c.*3167C>T | 3'UTR (SNP) | VAF 60/134 reads (45%) | called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576379 C>T | 5'Flank (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- BMF | c.*99dup | 3'UTR (INS) | VAF 52/106 reads (49%) | called by mutect2, varscan2
- BRD8 | c.788-121C>A | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, varscan2
- C8orf34 | c.1105+1440G>A | Intron (SNP) | VAF 27/171 reads (16%) | catalogued as rs1253611885; called by muse, mutect2, varscan2
- C8orf34 | c.*537C>T | 3'UTR (SNP) | VAF 13/74 reads (18%) | catalogued as rs941014452; called by muse, mutect2, varscan2
- CDK6 | c.*5518A>C | 3'UTR (SNP) | VAF 29/204 reads (14%) | called by muse, mutect2, varscan2
- CHM | c.*388C>T | 3'UTR (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- CHRDL1 | c.*1843G>A | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- CLEC12A | c.*485G>A | 3'UTR (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- CNOT1 | c.102+76G>A | Intron (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- CPNE6 | c.-4-12C>T | Intron (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- CPQ | c.*121A>T | 3'UTR (SNP) | VAF 68/385 reads (18%) | catalogued as rs1034733211; called by muse, mutect2, varscan2
- CRIM1 | c.332-18022G>A | Intron (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- CRYZL1 | c.904+497G>A | Intron (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2, varscan2
- CTSC | c.318+6731C>T | Intron (SNP) | VAF 83/181 reads (46%) | catalogued as rs752407638; called by muse, mutect2, varscan2
- CXCR6 | c.*326G>C | 3'UTR (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- DBF4 | chr7:87876468 C>T | 5'Flank (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- DBF4 | chr7:87876469 G>T | 5'Flank (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- DHRS7B | c.-39C>T | 5'UTR (SNP) | VAF 106/210 reads (50%) | catalogued as rs764853081; called by muse, mutect2, varscan2
- DIPK2B | c.499-6233A>T | Intron (SNP) | VAF 13/237 reads (5%) | called by muse, mutect2
- DISC1 | c.1981+80C>T | Intron (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- DUS4L | c.*381C>T | 3'UTR (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- ERICH1 | c.1258+786G>A | Intron (SNP) | VAF 150/290 reads (52%) | catalogued as rs542208788; called by muse, mutect2, varscan2
- EVL | c.1213+18G>T | Intron (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- F11 | c.485+139T>A | Intron (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- FAIM2 | c.*622C>T | 3'UTR (SNP) | VAF 123/253 reads (49%) | called by muse, mutect2, varscan2
- FAM229B | c.*1972C>G | 3'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- FAM241B | c.*519A>T | 3'UTR (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2
- FANCD2 | c.696-773G>A | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- FGD3 | c.*609G>A | 3'UTR (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- FMNL3 | c.*3323G>C | 3'UTR (SNP) | VAF 38/64 reads (59%) | called by muse, mutect2, varscan2
- FRAS1 | c.5856+446G>T | Intron (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- GABRG2 | c.-66T>G | 5'UTR (SNP) | VAF 138/251 reads (55%) | called by muse, mutect2, varscan2
- GHR | c.*2083C>T | 3'UTR (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- GLCCI1 | c.*214C>T | 3'UTR (SNP) | VAF 61/156 reads (39%) | called by muse, mutect2, varscan2
- GLIS3 | c.*1272C>T | 3'UTR (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- GNPTG | c.53-12C>T | Intron (SNP) | VAF 35/50 reads (70%) | called by muse, mutect2, varscan2
- GPAT4 | c.*898C>T | 3'UTR (SNP) | VAF 101/186 reads (54%) | called by muse, mutect2, varscan2
- GPD1 | c.*945G>A | 3'UTR (SNP) | VAF 31/292 reads (11%) | called by muse, mutect2, varscan2
- HOXD3 | chr2:176174422 G>T | 3'Flank (SNP) | VAF 40/136 reads (29%) | called by muse, mutect2, varscan2
- HSPB8 | c.*573T>C | 3'UTR (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- IFFO2 | c.*2364C>T | 3'UTR (SNP) | VAF 36/187 reads (19%) | catalogued as rs760015117; called by muse, mutect2, varscan2
- IRAG1 | c.67+38C>A | Intron (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- IYD | c.688-1798G>T | Intron (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- JMJD4 | c.961-100G>A | Intron (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- KLHL9 | c.*975G>T | 3'UTR (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- LAMB1 | c.*102T>G | 3'UTR (SNP) | VAF 13/423 reads (3%) | called by muse, mutect2
- LINC02870 | n.588C>T | RNA (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- LONRF2 | c.*10580A>C | 3'UTR (SNP) | VAF 55/122 reads (45%) | called by muse, mutect2, varscan2
- LRBA | c.*1025G>A | 3'UTR (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- LTBR | c.802-117G>C | Intron (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- MAB21L4 | c.515-115C>T | Intron (SNP) | VAF 33/138 reads (24%) | catalogued as rs922874991; called by muse, mutect2, varscan2
- MAP3K20 | c.988-5078G>A | Intron (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- MAP4K4 | chr2:101891739 T>G | 3'Flank (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- MAP9 | c.*2122T>G | 3'UTR (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- MATN1 | c.442-303C>G | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- MIA3 | c.3609+36C>G | Intron (SNP) | VAF 55/211 reads (26%) | called by muse, mutect2, varscan2
- MLLT10 | c.240+18261T>C | Intron (SNP) | VAF 38/78 reads (49%) | catalogued as rs1015456299; called by muse, mutect2, varscan2
- MRRF | c.459+323G>T | Intron (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2
- MSL3 | c.*319C>A | 3'UTR (SNP) | VAF 39/39 reads (100%) | called by muse, mutect2, varscan2
- MYCBP2 | c.8027-149del | Intron (DEL) | VAF 15/52 reads (29%) | catalogued as rs1379398533; called by mutect2, pindel, varscan2
- MYO16 | c.-39+33541G>A | Intron (SNP) | VAF 101/205 reads (49%) | catalogued as COSV100762972; called by muse, mutect2, varscan2
- NAIF1 | c.*1640A>T | 3'UTR (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- NBEAL1 | c.*760G>T | 3'UTR (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- NFIB | c.*730G>T | 3'UTR (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- NHLH2 | c.-338+113A>G | Intron (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1263G>T | RNA (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- NOS1 | c.*2507A>G | 3'UTR (SNP) | VAF 85/86 reads (99%) | called by muse, mutect2, varscan2
- NPY2R | c.*498G>T | 3'UTR (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- NRIP2 | c.*381C>G | 3'UTR (SNP) | VAF 54/188 reads (29%) | called by muse, mutect2, varscan2
- OR4A4P | n.501T>C | RNA (SNP) | VAF 103/192 reads (54%) | called by muse, mutect2, varscan2
- ORC4 | c.*288C>T | 3'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- OSBPL6 | c.*160C>G | 3'UTR (SNP) | VAF 18/384 reads (5%) | called by muse, mutect2
- PAQR5 | c.*129T>C | 3'UTR (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- PAX3 | chr2:222200556 T>C | 3'Flank (SNP) | VAF 49/110 reads (45%) | called by muse, mutect2, varscan2
- PDE6B | c.993-98C>T | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- PELI1 | c.*1872T>G | 3'UTR (SNP) | VAF 28/178 reads (16%) | called by muse, mutect2, varscan2
- PHYH | chr10:13302058 G>A | 5'Flank (SNP) | VAF 91/179 reads (51%) | catalogued as rs1017656647; called by muse, mutect2, varscan2
- PIK3C2G | c.*299T>A | 3'UTR (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2
- PLEKHS1 | c.-56G>A | 5'UTR (SNP) | VAF 63/295 reads (21%) | called by muse, mutect2, varscan2
- PPP1R1B | c.*163C>A | 3'UTR (SNP) | VAF 29/285 reads (10%) | called by muse, mutect2, varscan2
- PRDM5 | c.300+15658dup | Intron (INS) | VAF 19/160 reads (12%) | called by mutect2, pindel, varscan2
- PSMD5 | c.*1345C>T | 3'UTR (SNP) | VAF 34/219 reads (16%) | called by muse, mutect2, varscan2
- PTPRC | c.*440C>G | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- PTPRD | c.*3041C>A | 3'UTR (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+5095C>G | Intron (SNP) | VAF 31/224 reads (14%) | called by muse, mutect2, varscan2
- RASSF2 | c.*1895C>T | 3'UTR (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2, varscan2
- RBM12 | c.*2057C>T | 3'UTR (SNP) | VAF 19/223 reads (9%) | called by muse, mutect2
- RBM3 | c.*44G>A | 3'UTR (SNP) | VAF 60/234 reads (26%) | called by muse, mutect2, varscan2
- RIOX2 | c.785+49G>A | Intron (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- RN7SL860P | chr19:22601938 del AGG | 3'Flank (DEL) | VAF 4/34 reads (12%) | catalogued as rs1168144540; called by pindel, varscan2*
- RNF152 | c.*1177G>C | 3'UTR (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- RRP8 | c.*3495C>T | 3'UTR (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- RSF1 | c.*2406G>C | 3'UTR (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- RSU1 | c.*806G>A | 3'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- SAA2 | chr11:18242757 G>C | 3'Flank (SNP) | VAF 37/170 reads (22%) | called by muse, mutect2, varscan2
- SCAMP4 | c.*1624C>A | 3'UTR (SNP) | VAF 28/71 reads (39%) | called by mutect2, varscan2
- SFXN3 | c.881+67C>G | Intron (SNP) | VAF 74/122 reads (61%) | called by muse, mutect2, varscan2
- SGMS2 | chr4:107911636 C>T | 3'Flank (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- SGMS2 | chr4:107914732 G>A | 3'Flank (SNP) | VAF 90/173 reads (52%) | called by mutect2, varscan2
- SHANK2 | c.1174+33069C>G | Intron (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2, varscan2
- SIN3B | c.2956-63G>C | Intron (SNP) | VAF 16/143 reads (11%) | catalogued as rs898046747; called by muse, mutect2, varscan2
- SIX1 | c.*1352dup | 3'UTR (INS) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- SLC43A3 | c.185-127C>T | Intron (SNP) | VAF 14/267 reads (5%) | called by muse, mutect2
- SLC6A1 | c.371-103G>C | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- SLC9A1 | c.1485+161C>T | Intron (SNP) | VAF 45/351 reads (13%) | called by muse, mutect2, varscan2
- SNX29 | c.1402+9052C>T | Intron (SNP) | VAF 13/174 reads (7%) | catalogued as rs1445197216; called by muse, mutect2
- SORBS2 | c.3134+13_3134+15del | Intron (DEL) | VAF 118/248 reads (48%) | catalogued as rs748822434; called by pindel, varscan2
- TBXAS1 | c.333+2347del | Intron (DEL) | VAF 54/280 reads (19%) | called by mutect2, pindel, varscan2
- TCP10L3 | n.2719+1262G>T | Intron (SNP) | VAF 38/416 reads (9%) | called by muse, mutect2
- TENT5C | c.*321G>A | 3'UTR (SNP) | VAF 12/84 reads (14%) | catalogued as rs564656098; called by muse, mutect2, varscan2
- TENT5C | c.*716G>A | 3'UTR (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- TENT5C | c.*824G>A | 3'UTR (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- TENT5C | c.*1137G>A | 3'UTR (SNP) | VAF 14/106 reads (13%) | called by muse, varscan2
- TENT5C | c.*1355G>A | 3'UTR (SNP) | VAF 7/79 reads (9%) | catalogued as rs889082791; called by muse, mutect2
- TENT5C | c.*2619G>A | 3'UTR (SNP) | VAF 14/112 reads (13%) | called by muse, varscan2
- TENT5C | c.*2844G>A | 3'UTR (SNP) | VAF 24/157 reads (15%) | called by muse, varscan2
- TENT5C | c.*3098G>A | 3'UTR (SNP) | VAF 20/114 reads (18%) | called by muse, varscan2
- TENT5C | c.*3162G>A | 3'UTR (SNP) | VAF 25/130 reads (19%) | called by muse, varscan2
- TENT5C | c.*3333G>A | 3'UTR (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- TENT5C | c.*3634G>A | 3'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, varscan2
- TENT5C | c.*3765G>A | 3'UTR (SNP) | VAF 10/45 reads (22%) | called by muse, varscan2
- THSD7B | c.*326C>G | 3'UTR (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- TMEM196 | c.*799G>A | 3'UTR (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- TPK1 | c.501+70G>A | Intron (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- TRAPPC13 | c.*785C>T | 3'UTR (SNP) | VAF 28/128 reads (22%) | called by muse, mutect2, varscan2
- TRMT10B | c.574-131C>A | Intron (SNP) | VAF 10/39 reads (26%) | called by muse, varscan2
- TRNAU1AP | chr1:28578786 del G | 3'Flank (DEL) | VAF 70/171 reads (41%) | called by mutect2, pindel, varscan2
- TTC5 | c.*150C>G | 3'UTR (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- UNC13D | c.*557G>A | 3'UTR (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- UPF3A | c.*741A>G | 3'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, varscan2
- VSTM2A | c.*1231G>C | 3'UTR (SNP) | VAF 7/91 reads (8%) | called by muse, mutect2
- WFIKKN2 | c.*63C>G | 3'UTR (SNP) | VAF 40/71 reads (56%) | catalogued as COSV100260108; called by muse, mutect2, varscan2
- ZBTB10 | c.*1502A>C | 3'UTR (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3394+847G>T | Intron (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- ZFPL1 | c.-8-141A>T | Intron (SNP) | VAF 22/221 reads (10%) | called by muse, mutect2, varscan2
- ZNF592 | c.*1842G>C | 3'UTR (SNP) | VAF 6/101 reads (6%) | called by muse, mutect2
- ZNF765 | c.*2626G>A | 3'UTR (SNP) | VAF 122/335 reads (36%) | called by muse, mutect2, varscan2
